Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AALO, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AALO-01A (Primary Tumor).

Concerning

Summary pathology report

Left orchidectomy; nonseminoma (MT 100%); diameter 4 cm; no angio-invasion; no invasion of rete testis; tumor confined to testis.

Date of procurement (= date of orchidectomy):

ICD-O-3
Teratoma, mature 9080/0
Site (D) Testis NOS C62.9
AW 3/5/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 9908c8d9-5a9f-4d39-9dec-21dec56f2b04 (TCGA-2G-AALO.72E9FA0E-1F58-4B89-B893-1346E01A7A7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).